Gene-level copy-number profile of tumor specimen TCGA-AZ-4681-01A from TCGA case TCGA-AZ-4681, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.1 years (28,906 days).
Specimen TCGA-AZ-4681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.4b639d6e-cbad-4a3c-82f2-44a54c598d5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-4681-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4980704-10c3-480b-bd92-a5d0453978f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,060; copy number 2: 46,246; copy number 3: 5,808; copy number 4: 409; copy number 5: 11; copy number 6: 158; copy number 7: 89; copy number 8: 1; copy number 9: 23; copy number 11: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-4681-01A-01D-1406-01): tumor purity 0.88, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 296 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,269,704–38,382,272, 1 gene, copy number 11 (within-gene range 1–11): NSD3.
- chr8:38,335,981–40,016,391, 37 genes, copy number 8–11: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1.
- chr13:19,958,670–31,846,539, 257 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr13:31,952,580–31,953,361, 1 gene, copy number 6: EEF1DP3.

Autosomal genes at a single copy (total copy number 1): 7,060. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
